Somatic mutation profile of tumor specimen 0DAOSA from CCDI case PBBKFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,080 days).
Specimen 0DAOSA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 661094ef-ed80-4f15-ba05-53883ea0722f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOSB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/440f4198-384e-48c6-bad1-c22de29d1d71

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CES5A | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs751950787, COSV99307281; called by muse, mutect2, varscan2
- KRTAP21-1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 32/1046 reads (3%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.993); catalogued as COSV100624963; called by muse, mutect2
- NCOA2 | c.1896_1922del p.H633_L641del | In Frame Del (DEL) | VAF 46/315 reads (15%) | catalogued as rs769880905; called by mutect2, pindel, varscan2
- CHD4 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); called by muse, mutect2
- ERCC6L | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 106/450 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPOT | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 20/698 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZNF503 | c.1755G>A p.G585= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
